Somatic mutation profile of tumor specimen TCGA-LN-A7HY-01A (aliquot TCGA-LN-A7HY-01A-12D-A351-09) from TCGA case TCGA-LN-A7HY, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.1 years (18,296 days).
Specimen TCGA-LN-A7HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32be4271-1628-4321-9730-b6063779d97b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A7HY-10A (Blood Derived Normal), aliquot TCGA-LN-A7HY-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b352ee91-d841-467c-85eb-2471dad60b4a

The open-access MAF lists 165 somatic variants for this specimen: 125 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 37, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 2, Splice Region 1, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.656+1G>T p.X219_splice | Splice Site (SNP) | VAF 59/81 reads (73%) | catalogued as COSV52207826; called by muse, mutect2, varscan2
- ANKK1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs778503691, COSV100392904, COSV58273176; called by muse, mutect2, varscan2
- ASCC3 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV61228602; called by muse, mutect2, varscan2
- BACH1 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs763385315; called by muse, mutect2, varscan2
- BUB1B | c.2767G>T p.D923Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs760104068, COSV55015818; called by muse, mutect2, varscan2
- CCDC148 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV51772396; called by muse, mutect2, varscan2
- CD1B | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as rs912511686; called by muse, mutect2, varscan2
- CES1 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV62089644; called by muse, mutect2, varscan2
- CHD9 | c.3404A>G p.N1135S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255885860, COSV54613982; called by muse, mutect2, varscan2
- CNTNAP2 | c.1520A>C p.N507T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.113); catalogued as COSV62154563, COSV62237131; called by muse, mutect2, varscan2
- CSMD3 | c.4450G>T p.E1484* (on ENST00000297405 / NM_001363185.1; = p.E1380* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as COSV52151273; called by muse, mutect2, varscan2
- CSN2 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs781240580; called by muse, mutect2, varscan2
- EEF2 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100501044; called by muse, mutect2, varscan2
- EP300 | c.4384C>T p.R1462* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV54332184; called by muse, mutect2, varscan2
- EPHA2 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64454260; called by muse, mutect2, varscan2
- FOXG1 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57397112; called by muse, mutect2
- FRAT1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867690362; called by muse, mutect2, varscan2
- FRMD1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as rs775050650, COSV51961713; called by muse, mutect2, varscan2
- GAS6 | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59856728; called by muse, mutect2, varscan2
- H2AC12 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63616825; called by muse, mutect2, varscan2
- HS6ST1 | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1170245869; called by muse, mutect2, varscan2
- KIF26B | c.3215G>T p.S1072I | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63642521; called by muse, mutect2, varscan2
- KRTAP10-6 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100553247; called by muse, varscan2
- LRBA | c.6879T>A p.D2293E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as rs138518902; called by muse, mutect2, varscan2
- MTMR14 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs776656035, COSV56006176; called by muse, mutect2, varscan2
- MYLK | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs532659627, COSV60611222, COSV60615080, COSV60623949; called by muse, mutect2, varscan2
- MYO7A | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs782410686; called by muse, mutect2, varscan2
- MYO7B | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as rs760243996; called by muse, mutect2, varscan2
- NOC2L | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs747335515; called by muse, mutect2, varscan2
- P2RY10 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV50684758; called by muse, mutect2, varscan2
- PDPR | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV55350931; called by muse, mutect2, varscan2
- PHF14 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68856991; called by muse, mutect2, varscan2
- PKN1 | c.2332A>G p.T778A | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52875081; called by muse, mutect2
- PLXNA2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV65444241; called by muse, mutect2, varscan2
- PODN | c.786C>G p.N262K (on ENST00000395871; = p.N214K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV57011104; called by muse, mutect2, varscan2
- POM121L12 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.422); catalogued as COSV68694200; called by muse, mutect2, varscan2
- POU4F3 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV57942190; called by muse, mutect2, varscan2
- PRTFDC1 | c.654C>G p.H218Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV60773580; called by muse, mutect2, varscan2
- RELCH | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as rs780897375; called by muse, mutect2, varscan2
- RINT1 | c.883T>C p.S295P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1356970011; called by muse, mutect2, varscan2
- RXFP1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1240199718, COSV100314330; called by muse, mutect2, varscan2
- RYK | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs768567317; called by muse, mutect2, varscan2
- SACS | c.6497G>A p.R2166H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs200888451; called by muse, mutect2, varscan2
- SLC17A9 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs1377020679; called by muse, mutect2, varscan2
- SLC22A25 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1207804256; called by muse, mutect2, varscan2
- SLC7A4 | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100298483; called by muse, mutect2, varscan2
- SMURF1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs371859465, COSV63157556, COSV63159073; called by muse, mutect2, varscan2
- ST18 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs533229892, COSV52488443; called by muse, mutect2, varscan2
- TESK1 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1184513741; called by muse, mutect2, varscan2
- TP53 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 39/63 reads (62%) | catalogued as COSV52760587, COSV52765100, COSV53340164, COSV53452066; called by muse, mutect2, varscan2
- TRPC4 | c.1204G>T p.V402F | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58996905; called by muse, mutect2, varscan2
- VRK2 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs943968000; called by muse, mutect2, varscan2
- ZNF665 | c.349G>A p.E117K (on ENST00000600412; = p.E182K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as COSV67215123; called by muse, mutect2, varscan2
- ABCB5 | c.2626A>G p.I876V (on ENST00000404938 / NM_001163941.2; = p.I431V on NM_178559.6) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABHD14B | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- AC245033.1 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ADAM12 | c.2560C>G p.P854A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM29 | c.1109G>T p.S370I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2B2 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GAT2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- B4GALT3 | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C2orf68 | c.33C>A p.H11Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBFA2T2 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.084); called by muse, mutect2
- CCDC102B | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CDH12 | c.1580G>C p.R527T | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, mutect2
- CEP290 | c.4674G>T p.K1558N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CIPC | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- COCH | c.558C>A p.F186L (on ENST00000216361 / NM_001347720.1; = p.F121L on NM_004086.3) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- COL9A2 | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CRIM1 | c.931A>C p.I311L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CX3CR1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CYP1A1 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DIDO1 | c.3547G>C p.E1183Q | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DNAH5 | c.12349A>T p.I4117L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EPS8 | c.2221C>G p.P741A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EWSR1 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAIM | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM43B | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCAMR | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GRIA2 | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- GRIN2B | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC4 | c.1241C>G p.P414R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IFI16 | c.562_568del p.V188Nfs*4 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel
- IL1F10 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LIPH | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 77/108 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MED13 | c.5658G>T p.Q1886H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MIDEAS | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIOS | c.1846A>G p.R616G | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NAA15 | c.1590G>C p.M530I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NIBAN2 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NOD1 | c.1274T>G p.F425C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRDC | c.764+2T>A p.X255_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- NXPH2 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR2W1 | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PAPPA2 | c.4285C>T p.L1429F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- PDCD6IP | c.2362C>G p.Q788E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4D | c.619T>C p.S207P (on ENST00000340635 / NM_001104631.2; = p.S71P on NM_006203.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PEAK1 | c.628A>T p.I210F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PLEKHM2 | c.2920C>G p.Q974E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PLXNA3 | c.4327A>T p.I1443F | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXND1 | c.1851+1G>C p.X617_splice | Splice Site (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.933_939del p.E311Dfs*3 (on ENST00000359201; = p.E351Dfs*3 on NM_013397.6) | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- PURB | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- PXYLP1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- RPUSD4 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SFXN5 | c.535-1G>C p.X179_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2
- SLC16A1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC38A1 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SOGA3 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA17 | c.243A>T p.V81= | Splice Region (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- TCF20 | c.3731A>T p.D1244V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TDRD6 | c.2399C>G p.T800S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMPO | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNKS2 | c.2679A>G p.I893M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TNNT2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TOGARAM1 | c.5127G>C p.E1709D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TRIML1 | c.552A>T p.K184N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- UGT2B4 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WASHC4 | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ZBTB39 | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF302 | c.508G>A p.E170K (on ENST00000627982; = p.E91K on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2
- ZNF496 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); called by muse, mutect2
- ZNF563 | c.527A>T p.K176I | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF678 | c.1541A>C p.E514A | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- AMY2B | c.81T>C p.S27= | Silent (SNP) | VAF 89/202 reads (44%) | called by muse, mutect2, varscan2
- ATAD2 | c.2466A>G p.V822= | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- BMP6 | c.1428G>A p.P476= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs937163458, COSV99307230; called by muse, mutect2, varscan2
- DHRS2 | c.840C>G p.L280= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs144980250; called by muse, mutect2, varscan2
- DHX9 | c.2757A>G p.L919= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- DNAH5 | c.12423A>G p.T4141= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs756382401; called by muse, varscan2
- DYRK4 | c.390G>A p.V130= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- FAM83G | c.2313C>T p.T771= | Silent (SNP) | VAF 77/122 reads (63%) | catalogued as rs1381910905; called by muse, mutect2, varscan2
- FBLN2 | c.2445G>A p.T815= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs370055863; called by muse, mutect2, varscan2
- GALNTL5 | c.1083C>A p.I361= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV67179777, COSV67181171; called by muse, mutect2, varscan2
- GHRHR | c.54G>C p.P18= | Silent (SNP) | VAF 43/143 reads (30%) | called by muse, mutect2, varscan2
- HACD2 | c.198T>A p.A66= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- ISOC2 | c.486A>G p.E162= (on ENST00000425675 / NM_001136201.2; = p.E178= on NM_024710.3) | Silent (SNP) | VAF 55/137 reads (40%) | called by muse, mutect2, varscan2
- KSR2 | c.1575G>A p.T525= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs756688718; called by muse, mutect2, varscan2
- LMX1A | c.189C>A p.A63= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- MAP3K8 | c.561C>T p.H187= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs569267728, COSV99552292; called by muse, mutect2, varscan2
- MDM2 | c.732G>A p.Q244= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1177697478; called by muse, mutect2, varscan2
- MUC16 | c.35943A>G p.T11981= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- MYO1F | c.2955G>C p.P985= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100597136; called by muse, mutect2, varscan2
- NAGLU | c.1137G>T p.L379= | Silent (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- NFYB | c.168T>C p.D56= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs762750390; called by muse, mutect2, varscan2
- NOS2 | c.2463C>A p.P821= | Silent (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- OAT | c.306G>A p.K102= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100920422, COSV100920438; called by muse, mutect2, varscan2
- OR5K4 | c.777T>C p.I259= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- OR8B4 | c.390C>A p.L130= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- OTOGL | c.3915G>A p.R1305= (on ENST00000547103; = p.R1296= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1938C>T p.F646= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs377558165; called by muse, mutect2, varscan2
- PLOD1 | c.729C>T p.N243= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs567164584, COSV52140360; called by muse, mutect2, varscan2
- PPP1R13B | c.1110C>G p.L370= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- RTRAF | c.393G>A p.K131= | Silent (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- SERINC2 | c.828C>G p.L276= (on ENST00000373709 / NM_178865.5; = p.L280= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- SHPRH | c.3654A>G p.P1218= (on ENST00000275233 / NM_001042683.3; = p.P1222= on NM_173082.3) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs1490981879; called by muse, mutect2, varscan2
- SHROOM3 | c.2577C>G p.S859= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- SLC9A9 | c.237T>G p.T79= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs1036914624; called by muse, mutect2, varscan2
- SMC2 | c.393C>T p.F131= | Silent (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- WNK2 | c.555C>T p.A185= | Silent (SNP) | VAF 105/163 reads (64%) | catalogued as rs1264462365, COSV52938472, COSV52944160; called by muse, mutect2, varscan2
- Z83844.2 | c.1617C>T p.P539= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1185050850, COSV53217467; called by muse, mutect2, varscan2
- HERC2P3 | n.490G>T | RNA (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- MAP2K4 | c.393+428C>T | Intron (SNP) | VAF 27/57 reads (47%) | catalogued as rs572154384, COSV100796332; called by muse, mutect2, varscan2
- PDZD3 | c.-78T>C | 5'UTR (SNP) | VAF 50/89 reads (56%) | called by muse, mutect2, varscan2
